Surgical pathology report (de-identified scan), TCGA case TCGA-69-8254, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-8254-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] M

SPECIMEN SUBMITTED:

RIGHT LOWER LOBE LUNG RESECTION

Final Diagnosis

Right lung, lower lobe, wedge resection - Adenocarcinoma, papillary predominant with acinar (30%), micropapillary (10%) and lepidic (10%) patterns.

- Centrilobular emphysema.
- Organizing pneumonia.

Diagnosis Comment:

The tumor size is Tumor Size: 5.5 x 3 x 2 cm. The parenchymal margin is negative for neoplasm. Invasion into the overlying pleura will be assessed with Movats stains and the results of those studies reported as an addendum. The tumor will be send for EGFR mujtational analysis and the results of those studies reported as an addendum.

Intraoperative Diagnosis:

A. Inked parenchymal margin negative. Tumor: atypical, suspicious for adenocarcinoma in situ

Clinical Diagnosis:

RIGHT LOWER LOBE MASS

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received in formalin labeled "right lower lobe lung resection" is a specimen consisting of a lung wedge measuring 15.2 x 5.5 x 2.3 cm, and weighing 77 grams. The parenchymal margin is inked orange, and the pleural surface is partially inked blue. The pleural surface is smooth with anthracotic pigmentation and a focal area of puckering at the site of a surgical stitch (the wedge split during extraction). On sectioning the specimen, a tan gelatinous area of consolidation with a friable cavity is identified abutting the pleura under the area of the stitch. The whole area of consolidation and cavity measures 5.5 x 3 x 2 cm. A tan firm lobulated mass within this area measures 3.3 x 2 x 1.2 cm. The area of consolidation extends to 0.1 cm from the resection margin inked orange. The remainder of the lung parenchyma shows areas of atelectasis and hemorrhage. A small tan firm nodule measuring 0.2 cm is present separate from the area of consolidation, and is located 1.5 cm from it. Sections are submitted as follows: FSA1 resection margin for frozen evaluation, FSA2 tumor for frozen evaluation, A3-A14 consolidating area with adjacent pleura (totally submitted) and resection margin (orange), A8-A13 cavity; A9-A10 closest resection margin; A15 separate nodule.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 9270713e-c599-4f50-b260-a8f27abc5722 (TCGA-69-8254.3EDEAFC6-1876-4547-82B2-90E18240061D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).